Somatic mutation profile of tumor specimen TCGA-2G-AAKG-01A (aliquot TCGA-2G-AAKG-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAKG, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 22.9 years (8,353 days).
Specimen TCGA-2G-AAKG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 186fb2e2-e25a-462e-9df8-7fd69c3b821a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAKG-10A (Blood Derived Normal), aliquot TCGA-2G-AAKG-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4033355c-2b80-4ae6-9c55-9e1269842346

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, Intron 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GOLGA8B | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as rs756682773; called by mutect2, varscan2
- GPNMB | c.12_13del p.Y5Lfs*15 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | catalogued as rs1177347830; called by pindel, varscan2
- HSF4 | c.1471T>C p.S491P (on ENST00000521374 / NM_001040667.3; = p.S461P on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.38); catalogued as COSV50460298; called by muse, mutect2
- IQCF6 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs370141442; called by muse, mutect2
- NEB | c.9319G>A p.D3107N | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs377180119; called by muse, mutect2, varscan2
- SELENOO | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs760826494; called by muse, mutect2, varscan2
- WASHC2A | c.3955C>T p.P1319S | Missense Mutation (SNP) | VAF 114/411 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs780992644; called by muse, mutect2, varscan2
- ZFHX4 | c.9715G>A p.D3239N | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1227663100, COSV50642938, COSV50846359; called by muse, mutect2, varscan2
- DCLRE1B | c.82T>A p.F28I | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EBF1 | c.1058A>G p.D353G | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- KIDINS220 | c.2552A>G p.N851S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC2 | c.2535G>T p.K845N | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- MYEF2 | c.967A>G p.K323E | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYH8 | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLN | c.1981-1G>T p.X661_splice | Splice Site (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- RPL5 | c.175_176del p.D59Yfs*53 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by pindel, varscan2
- SYMPK | c.1007C>G p.A336G | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF592 | c.970A>C p.K324Q | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ZNF592 | c.1498C>A p.P500T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BRINP2 | c.1309C>T p.L437= | Silent (SNP) | VAF 61/273 reads (22%) | catalogued as COSV100838030; called by muse, mutect2, varscan2
- CASR | c.1809C>T p.R603= (on ENST00000490131; = p.R680= on NM_000388.4) | Silent (SNP) | VAF 55/141 reads (39%) | called by muse, mutect2, varscan2
- DISP2 | c.576G>A p.R192= | Silent (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- RPL13A | c.342+30_342+44del | Intron (DEL) | VAF 25/111 reads (23%) | called by mutect2, pindel, varscan2
- ST3GAL3 | c.506+42G>C | Intron (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
